Gene-level copy-number profile of tumor specimen TCGA-24-1423-01A from TCGA case TCGA-24-1423, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,281 days).
Specimen TCGA-24-1423-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.27599998-8559-4f7e-8288-6fdf8586e61a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1423-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f131125-b9b9-4c5d-a097-2858b032282a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 2: 16,668; copy number 3: 726; copy number 4: 29,288; copy number 5: 312; copy number 6: 10,542; copy number 7: 918; copy number 8: 1,143; copy number 9: 37; copy number 10: 164.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1423-01A-01D-0472-01): tumor purity 0.93, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:93,820,171–94,757,681, 11 genes (within-gene range 0–2): RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT.
- chr17:31,090,787–31,382,116, 9 genes: AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 201 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:69,457,997–69,674,349, 1 gene, copy number 9 (within-gene range 6–9): AAK1.
- chr2:69,594,741–70,125,317, 16 genes, copy number 9: RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816.
- chr3:113,828,182–114,310,288, 17 genes, copy number 9: GRAMD1C, AC079944.1, AC079944.2, VPS26AP1, AC128687.2, ZDHHC23, CCDC191, AC128687.1, AC128687.3, AC092896.1, QTRT2, H2BP3, DRD3, AC093010.1, FAM214BP1, ZNF80, TIGIT.
- chr3:114,314,501–114,388,978, 3 genes, copy number 9: AC093010.2, MIR568, ZBTB20-AS1.
- chr8:121,954,640–132,481,095, 164 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
